CCDI case PBBKZS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3dc1f764-aca4-494e-bdc1-adcca7e496b0

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.7 years (3,553 days).

Biospecimens (3 samples)
- Sample 0DBD0L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBD0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBD0V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
